Gene-level copy-number profile of tumor specimen C3N-06044-01 from CPTAC case C3N-06044, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 65.6 years (23,945 days).
Specimen C3N-06044-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1ad943d-6be2-4855-94ff-d271c574d71d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06044-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/5c7d9509-af78-4534-864f-17cf28c35c44

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 30,188; copy number 2: 23,496; copy number 3: 1,724; copy number 4: 2,904; copy number 5: 12; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,035,769–46,124,054, 1 gene: GABRG1.
- chr4:106,041,599–106,316,683, 1 gene (within-gene range 0–1): TBCK.
- chr5:86,335,024–86,402,960, 4 genes: AC016550.1, AC016550.2, AC016550.3, AC026444.1.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr8:64,091–2,556,440, 49 genes: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, DLGAP2-AS1, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1.
- chr10:1,361,001–1,361,637, 1 gene (within-gene range 0–1): AL513304.1.
- chr10:5,093,408–5,218,949, 6 genes (within-gene range 0–1): U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2.
- chr10:36,089,086–36,089,389, 1 gene: AL355300.1.
- chr14:20,110,739–20,149,745, 3 genes: OR4K17, OR4N5, PSMB7P1.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–1): RNU6-457P.
- chr17:22,671,433–22,706,703, 2 genes (within-gene range 0–1): AC131274.3, AC131274.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,643 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:70,258,999–70,445,536, 6 genes, copy number 3: ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1.
- chr2:89,019,992–89,020,686, 1 gene, copy number 3 (within-gene range 2–3): IGKV2-10.
- chr2:89,040,224–91,880,195, 87 genes, copy number 3 (broad region; genes not listed).
- chr2:94,725,674–94,738,249, 3 genes, copy number 3: CNN2P11, GXYLT1P7, CNN2P8.
- chr6:60,281,444–60,546,660, 1 gene, copy number 4: AC244258.1.
- chr7:37,032–102,464,863, 1,858 genes, copy number 4 (within-gene range 4–5) (broad region; genes not listed).
- chr7:102,479,976–159,233,377, 1,071 genes, copy number 3–4 (broad region; genes not listed).
- chr9:61,789,143–63,143,401, 46 genes, copy number 3: RN7SL722P, FAM27C, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4.
- chr9:63,703,065–68,330,626, 95 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr14:18,333,726–18,412,264, 3 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2.
- chr14:19,199,763–19,269,380, 6 genes, copy number 3: AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1.
- chr16:46,469,341–46,698,394, 12 genes, copy number 3: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6.
- chr20:87,250–64,327,972, 1,401 genes, copy number 3 (broad region; genes not listed).
- chr21:8,996,496–9,129,752, 6 genes, copy number 3: CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,397,644–13,120,807, 13 genes, copy number 3–5: AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:15,282,557–15,350,043, 5 genes, copy number 3: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.
- chr22:18,178,038–18,894,407, 29 genes, copy number 3: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 27,850. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
